MMRF case MMRF_2341 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4ffcbb59-123b-4494-bd0a-b3932bbc0704

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.7 years (19,625 days); ISS stage: II; Days to last known disease status: 86 days; Days to last follow up: 86 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 2.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.84 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 8.1 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 86: M Protein 1.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.687 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.111 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -6: Weight: 85 kg; Height: 171 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2341_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2341_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
